Somatic mutation profile of tumor specimen TCGA-60-2712-01A (aliquot TCGA-60-2712-01A-01W-0877-08) from TCGA case TCGA-60-2712, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 79.8 years (29,131 days).
Specimen TCGA-60-2712-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f82c66dc-68e2-488f-8197-23dff88394d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2712-11A (Solid Tissue Normal), aliquot TCGA-60-2712-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9ff8f38-85b4-43b0-9665-605d38da1435

The open-access MAF lists 78 somatic variants for this specimen: 55 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 19, Splice Site 3, Intron 3, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1, Splice Region 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 93/387 reads (24%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ASB17 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52412050; called by muse, mutect2, varscan2
- CADM2 | c.495G>T p.E165D (on ENST00000407528 / NM_001167674.2; = p.E167D on NM_153184.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV67403053; called by muse, mutect2, varscan2
- CAMSAP1 | c.4345G>T p.A1449S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.384); catalogued as COSV100409518, COSV56728343; called by muse, varscan2
- CCDC57 | c.1338G>T p.E446D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58937180; called by muse, mutect2, varscan2
- CD1E | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as rs1396447226, COSV63772830; called by mutect2, varscan2
- CDC25B | c.881G>C p.S294T (on ENST00000245960 / NM_021873.3; = p.S280T on NM_004358.4) | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV55659476; called by muse, mutect2, varscan2
- CHI3L1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as rs372451627; called by muse, mutect2, varscan2
- CLSTN2 | c.929G>C p.C310S | Missense Mutation (SNP) | VAF 322/1141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71724966; called by muse, mutect2, varscan2
- CRX | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs142111462, COSV55759068; called by muse, mutect2, varscan2
- CRYGA | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs559628404, COSV58019145; called by muse, mutect2, varscan2
- DCTN1 | c.2182C>G p.Q728E | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV62621471; called by muse, mutect2, varscan2
- DMXL1 | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV60720591; called by muse, mutect2, varscan2
- DNAH11 | c.5501G>A p.R1834H | Missense Mutation (SNP) | VAF 200/1824 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs750430725, COSV60945433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP10 | c.200C>G p.T67S | Missense Mutation (SNP) | VAF 87/490 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59725645; called by muse, mutect2, varscan2
- DZANK1 | c.1744G>A p.E582K (on ENST00000262547 / NM_001099407.1; = p.E389K on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52756953; called by muse, mutect2, varscan2
- EIF4B | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV50407761; called by muse, mutect2, varscan2
- EPAS1 | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55390256; called by muse, mutect2, varscan2
- ERBB4 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53585637; called by muse, mutect2, varscan2
- FGD3 | c.1182+2T>C p.X394_splice | Splice Site (SNP) | VAF 12/105 reads (11%) | catalogued as COSV100490781; called by muse, mutect2, varscan2
- FOXP1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 50/190 reads (26%) | catalogued as COSV59554443; called by muse, mutect2, varscan2
- HAL | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs779523127, COSV54120292; called by muse, mutect2
- KIAA1109 | c.8470G>C p.E2824Q | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52691497; called by muse, mutect2, varscan2
- KIF18A | c.1949-1G>T p.X650_splice | Splice Site (SNP) | VAF 18/64 reads (28%) | catalogued as COSV54187466; called by muse, mutect2, varscan2
- KIF6 | c.817A>C p.I273L | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54693893; called by muse, mutect2, varscan2
- MACF1 | c.11881G>A p.E3961K (on ENST00000372915; = p.E1894K on NM_012090.5) | Missense Mutation (SNP) | VAF 33/205 reads (16%) | catalogued as COSV57143301; called by muse, mutect2, varscan2
- MAP2 | c.3725A>G p.Q1242R | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200382253, COSV52307413; called by muse, mutect2, varscan2
- MYO3A | c.4001G>T p.R1334M | Missense Mutation (SNP) | VAF 113/455 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as COSV56347105, COSV56348641; called by muse, mutect2, varscan2
- NCAN | c.2327A>T p.D776V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.202); catalogued as COSV53058496; called by muse, mutect2, varscan2
- NPSR1 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 156/612 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV62207450; called by muse, mutect2, varscan2
- OR5K4 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 151/1533 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61584310; called by muse, mutect2
- OR8B8 | c.833A>T p.Y278F | Missense Mutation (SNP) | VAF 87/328 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60145699; called by muse, mutect2, varscan2
- PCDH15 | c.5073T>A p.S1691R | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV57390803; called by muse, mutect2, varscan2
- PCED1A | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV62314160; called by muse, mutect2, varscan2
- PIK3CG | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs927963993, COSV63253424; called by muse, mutect2, varscan2
- PLEKHO1 | c.732G>T p.W244C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV50311328; called by muse, mutect2, varscan2
- PRSS35 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs751533715, COSV63800555, COSV63801183; called by muse, mutect2, varscan2
- PUS7L | c.1301T>G p.F434C | Missense Mutation (SNP) | VAF 78/422 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61262959; called by muse, mutect2, varscan2
- RIN3 | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754628613, COSV53655182; called by muse, mutect2, varscan2
- SATB2 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 124/445 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs765504446, COSV53492391, COSV99611217; called by muse, mutect2, varscan2
- SCLY | c.802-1G>A p.X268_splice (on ENST00000651534; = p.X260_splice on NM_016510.7) | Splice Site (SNP) | VAF 30/136 reads (22%) | catalogued as COSV54544313; called by muse, mutect2, varscan2
- SIRT2 | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs200563255, COSV50877222; called by muse, mutect2, varscan2
- SLC38A2 | c.1233G>T p.W411C | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.537); catalogued as rs779347880, COSV56746423; called by muse, mutect2, varscan2
- TTN | c.18325G>C p.V6109L (on ENST00000591111; = p.V5182L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | PolyPhen benign (0); catalogued as COSV59960199, COSV60337670; called by muse, mutect2, varscan2
- USF3 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV57077246; called by muse, mutect2, varscan2
- VCPIP1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60047413, COSV60050141; called by muse, mutect2, varscan2
- ZCCHC2 | c.2096A>C p.E699A | Missense Mutation (SNP) | VAF 249/800 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.174); catalogued as COSV54040976; called by muse, mutect2, varscan2
- ZNF443 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 213/1002 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56894268; called by muse, mutect2, varscan2
- ZNF479 | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs1554400213, COSV100482446, COSV58643443; called by muse, mutect2, varscan2
- LRRN4 | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); called by mutect2, varscan2
- PDE8B | c.770_786del p.G257Vfs*7 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- PTOV1 | c.422_423insA p.M142Hfs*58 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- SMCR8 | c.2284_2289del p.K762_P763del | In Frame Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- SMG1 | c.4019T>C p.L1340S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- TRIML1 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.055); called by muse, mutect2
- FCGBP | c.2913G>A p.V971= | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as rs371925645; called by muse, mutect2, varscan2
- GALNT17 | c.651G>A p.V217= | Silent (SNP) | VAF 29/157 reads (18%) | catalogued as COSV100352451, COSV61190173; called by muse, mutect2, varscan2
- HOATZ | c.63G>T p.P21= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100239592; called by muse, mutect2, varscan2
- HUNK | c.369C>T p.I123= | Silent (SNP) | VAF 58/399 reads (15%) | catalogued as COSV54231986; called by muse, mutect2, varscan2
- ITGAE | c.21G>T p.L7= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV53999652; called by muse, varscan2
- KLF11 | c.1410G>T p.T470= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV59940560, COSV59941581; called by muse, mutect2, varscan2
- MAP4K4 | c.1905C>G p.S635= (on ENST00000347699 / NM_001242559.2; = p.S550= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV56340358; called by muse, mutect2
- OR5R1 | c.795T>C p.N265= | Silent (SNP) | VAF 37/328 reads (11%) | catalogued as COSV56573632; called by muse, mutect2, varscan2
- PLB1 | c.1542C>T p.D514= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV59835205; called by muse, mutect2, varscan2
- RYR1 | c.11107C>T p.L3703= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV62110309; called by muse, mutect2
- SEMA3E | c.186G>C p.L62= | Silent (SNP) | VAF 66/262 reads (25%) | catalogued as COSV57108165; called by muse, mutect2, varscan2
- SGK1 | c.9G>A p.V3= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV52814898; called by muse, mutect2, varscan2
- SLC26A11 | c.1738C>T p.L580= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2
- SPATA31E1 | c.2745C>A p.T915= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV57790793, COSV57793525; called by muse, mutect2, varscan2
- SYNJ1 | c.4758G>T p.P1586= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV59156390, COSV99050419; called by muse, mutect2, varscan2
- TM4SF19 | c.423T>C p.G141= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV56557627; called by muse, mutect2, varscan2
- TRPM1 | c.1827G>A p.Q609= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV56642188; called by muse, mutect2, varscan2
- TYRO3 | c.1326G>A p.T442= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs373237575; called by muse, mutect2, varscan2
- ZNF99 | c.318T>C p.C106= | Silent (SNP) | VAF 52/305 reads (17%) | catalogued as rs766877148, COSV68056707; called by muse, mutect2, varscan2
- BNC2 | c.2639+5592T>C | Intron (SNP) | VAF 80/164 reads (49%) | catalogued as COSV101034114; called by mutect2, varscan2
- MRPL22 | c.-2A>G | 5'UTR (SNP) | VAF 69/279 reads (25%) | catalogued as rs1044071127, COSV99501766; called by muse, mutect2, varscan2
- USH1C | c.1284+7629G>T | Intron (SNP) | VAF 16/40 reads (40%) | called by mutect2, varscan2
- USH1C | c.1284+7627dup | Intron (INS) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
